Somatic mutation profile of tumor specimen TCGA-KK-A7AZ-01A (aliquot TCGA-KK-A7AZ-01A-12D-A32B-08) from TCGA case TCGA-KK-A7AZ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.1 years (20,507 days).
Specimen TCGA-KK-A7AZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad2a4304-92a3-4eb8-a568-8a036ba4972f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A7AZ-11A (Solid Tissue Normal), aliquot TCGA-KK-A7AZ-11A-11D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d915755e-76a2-4078-a75d-58b6318838ca

The open-access MAF lists 34 somatic variants for this specimen: 28 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 21, Silent 6, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR2A | c.1295T>G p.V432G | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99604914; called by muse, mutect2
- AMBRA1 | c.2422C>T p.R808C (on ENST00000458649 / NM_001367468.1; = p.R718C on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54047977; called by muse, mutect2, varscan2
- CALCRL | c.1125C>A p.F375L | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV101131027, COSV66473737; called by muse, mutect2, varscan2
- CD180 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 106/259 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs372829866, COSV56520571; called by muse, mutect2, varscan2
- CEP170B | c.253G>A p.D85N (on ENST00000453495; = p.D15N on NM_015005.3) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101371580; called by muse, mutect2, varscan2
- CNOT1 | c.6770A>T p.D2257V | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55314449, COSV99800976; called by muse, mutect2, varscan2
- DSP | c.2990C>T p.A997V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.075); catalogued as COSV101131643; called by muse, mutect2
- EEF2 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as COSV100500933; called by muse, mutect2, varscan2
- EFCAB3 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.224); catalogued as COSV100540412; called by muse, mutect2, varscan2
- FAM172A | c.1153A>C p.I385L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV101232906; called by muse, mutect2, varscan2
- FBN3 | c.4362C>A p.N1454K | Missense Mutation (SNP) | VAF 98/229 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV99561589; called by muse, mutect2, varscan2
- KIF22 | c.1951-2A>T p.X651_splice | Splice Site (SNP) | VAF 10/284 reads (4%) | catalogued as COSV99361413; called by muse, mutect2
- MROH7 | c.1242T>G p.D414E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as COSV100273899; called by muse, mutect2, varscan2
- OCRL | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs749551841, COSV63981540; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- PEAK1 | c.1054T>A p.S352T | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.525); catalogued as COSV100433360; called by muse, mutect2, varscan2
- PLCG2 | c.3053A>G p.D1018G | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100842544; called by muse, mutect2, varscan2
- PNLIP | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as COSV100981937; called by muse, mutect2, varscan2
- SCARB2 | c.1246C>G p.H416D | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99358081; called by muse, mutect2, varscan2
- SIGLEC10 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs765309332, COSV100219251; called by muse, mutect2, varscan2
- SPTA1 | c.2671C>T p.R891* | Nonsense Mutation (SNP) | VAF 65/152 reads (43%) | catalogued as rs755630903, CM148356, COSV63749670; called by muse, mutect2, varscan2
- TG | c.5756G>A p.C1919Y | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99602600; called by muse, mutect2
- TRPM3 | c.347G>A p.R116H (on ENST00000357533 / NM_001366142.2; = p.R85H on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as rs201455474, COSV100625383; called by muse, mutect2, varscan2
- USP12 | c.708T>G p.C236W | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99997763; called by muse, varscan2
- YTHDF1 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.162); catalogued as COSV64833727; called by muse, mutect2, varscan2
- AMBRA1 | c.1412dup p.P473Sfs*8 (on ENST00000458649 / NM_001367468.1; = p.P383Sfs*8 on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 40/106 reads (38%) | called by mutect2, pindel, varscan2
- PECR | c.47T>A p.L16Q | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PPP2CA | c.491del p.F164Sfs*11 | Frame Shift Del (DEL) | VAF 45/119 reads (38%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.430_431dup p.G145Afs*43 | Frame Shift Ins (INS) | VAF 10/14 reads (71%) | called by mutect2, varscan2
- ACVR2A | c.1296T>A p.V432= | Silent (SNP) | VAF 14/212 reads (7%) | catalogued as COSV99604919; called by muse, mutect2
- CAND1 | c.2559A>T p.G853= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV101607349; called by muse, mutect2, varscan2
- HOPX | c.114C>G p.A38= (on ENST00000317745; = p.A56= on NM_032495.6) | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs941347493, COSV100497074; called by muse, mutect2
- SLC12A8 | c.2040C>T p.D680= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100102989; called by muse, mutect2, varscan2
- SLC9A3 | c.1245C>T p.R415= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs143761751, COSV99375879; called by muse, mutect2, varscan2
- VMP1 | c.522T>G p.T174= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV99230865; called by muse, mutect2
